Surgical pathology report (de-identified scan), TCGA case TCGA-22-4599, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-4599-01A (Primary Tumor).

Surgical Pathology

TISSUE DESCRIPTION:

Left lung (565 grams), superior mediastinal (left lower paratracheal, left tracheo-bronchial), aortic (aorto-pulmonary, anterior mediastinal), and inferior mediastinal (subcarinal, left inferior pulmonary ligament) lymph nodes

DIAGNOSIS:

Lung, left, pneumonectomy: Invasive grade 3 (of 4) squamous cell carcinoma forming a centrally located mass 2.8 x 2.0 x 1.2 cm involving the pulmonary artery. Post-obstructive pneumonia and pleuritis is also present. The pleura is not involved. The bronchial margin is free by 3 cm. Multiple (2) intrapulmonary peribronchial lymph nodes are negative for tumor.

Lymph nodes, superior and inferior mediastinal, excision: Multiple (3 left lower paratracheal, 1 tracheo-bronchial, 9 subcarinal, and 2 left inferior pulmonary ligament) lymph nodes are negative for tumor.

Lymph nodes, aortic, excision: Multiple (6 aorto-pulmonary, 2 anterior mediastinal) lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file ce9cae7d-163a-423d-8700-1a265184c64f (TCGA-22-4599.39E30903-77E8-47ED-9F00-64D4225F996D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).